Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A63V, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A63V-01A (Primary Tumor).

[page 1 of 7]
Pathology Report

Report Type
Date of Event ..
Sex M
Authored by
Hosp/Group
Record Status FINAL

ICD-0-3

Carcinoma, squamous
cell NOS 8070/3
Site: Buccal mucosa
C06.0
JW 5/10/13

FINAL DIAGNOSIS:

PART 1: BUCCAL MUCOSA, SKIN, UPPER AND LOWER LIP, LEFT, RESECTION
A. INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED
(4.0

CM), OF BUCCAL MUCOSA EXTENDING TO THE SKIN.

B. NO ANGIOLYMPHATIC INVASION OR PERINEURAL INVASION.

C. MARGINS ARE FREE OF CARCINOMA (see also other parts).

D. PATHOLOGIC STAGE: pT4a N0.

PART 2: LIP, RIGHT LOWER, BIOPSY

NO TUMOR PRESENT.

PART 3: MARGIN, ADDITIONAL MUCOSA CIRCUMFERENTIAL, BIOPSY

NO TUMOR PRESENT.

PART 4: LIP, LEFT UPPER, BIOPSY

NO TUMOR PRESENT.

PART 5: ALVEOLUS, LEFT UPPER, BIOPSY

NO TUMOR PRESENT.

PART 6: MARGIN, LEFT POSTERIOR BUCCAL, BIOPSY

NO TUMOR PRESENT.

PART 7: ALVEOLUS, LEFT LOWER, BIOPSY

NO TUMOR PRESENT.

PART 8: LIP, LEFT LOWER, BIOPSY

NO TUMOR PRESENT.

PART 9: MANDIBLE, LEFT, MARGINAL MANDIBULECTOMY

NO TUMOR PRESENT, MARGINS ARE FREE OF CARCINOMA.

PART 10: LYMPH NODES, LEFT NECK, LEVEL 1, SELECTIVE NECK DISSECTION
A. ELEVEN LYMPH NODES, NO TUMOR PRESENT (0/11).

B. UNREMARKABLE SUBMANDIBULAR GLAND.

PART 11: LYMPH NODES, LEFT NECK, LEVELS 2-4, SELECTIVE NECK DISSECTION
A. THIRTY FOUR LYMPH NODES, NO TUMOR PRESENT (0/34).

B. UNREMARKABLE PAROTID TISSUE.

Pathologist:

** Report Electronically Signed Out **

By Pathologist:

My signature is attestation that I have personally reviewed the
submitted
material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in eleven parts.

Part 1 is received fresh for intraoperative consultation labeled with
the

[page 2 of 7]
patient' s name, initials XX, medical record number and "left buccal resection take margins." It consists of a 7.0 x 5.0 x 4.0 cm portion of left cheek with portion of upper and lower lip in total. The buccal surface of the cheek shows a fungating, focally necrotic tumor measuring 4.0 x 3.0 cm and 3.8 cm in depth. The tumor is seen infiltrating into the skin of the cheek causing a defect measuring 1.1 x 1.0 cm. The tumor is situated within 0.1 cm of the inferior margin, 0.6 cm of the superior margin, and 0.2 cm of the posterior margin.

Gross photographs are taken. Tissue is banked.

Ink Code:

Black - posterior margin

Blue superior margin

Green inferior margin

Red banked area.

Section Code:

1A tumor in relation to the superior margin

1B tumor in relation to the inferior margin

1C tumor in relation to the posterior margin

1D tumor in relation to the defect

1E-1F tumor at the buccal surface

1G tumor with skin.

Time in formalin:

Part 2 is received fresh for intraoperative consultation labeled with the patient' s name, initials XX, medical record number and "right lower lip

biopsy." It consists of two fragments of grey tan tissue measuring 0.4 x 0.2

x 0.1 cm each which is submitted entirely in cassette labeled as 2AFS.

Time in formalin:

Part 3 is received fresh labeled with the patient' s name, initials XX, medical record number and "additional mucosal circumferential margin."

It consists of a 12.0 x 0.8 x 0.4 cm piece of grey tan tissue submitted entirely

in cassette labeled as 3A-3B.

Time in formalin:

Part 4 is received fresh labeled with the patient' s name, initials XX, medical record number and "left upper lip." It consists of a 2.2 x 0.4 x 0.3

piece of gray-tan tissue which is submitted entirely in cassette labeled as 4AFS.

Time in formalin:

Part 5 is received fresh for intraoperative consultation labeled with the patient' s name, initials XX, medical record number and "left upper alveolus."

It consists of a 2.8 x 0.3 x 0.2 cm piece of gray-tan tissue which is submitted entirely in cassette labeled as 5AFS.

[page 3 of 7]
Time in formalin:

Part 6 is received fresh labeled with the patient' s name, initials XX, medical record number and "left posterior buccal margin." It consists of two

fragments of tissue measuring 1.2 x 0.5 x 0.3 cm and 1.2 x 0.7 x 0.5 cm, which

is submitted entirely in cassette labeled 6AFS.

Time in formalin:

Part 7 is received fresh labeled with the patient' s name, initials XX, medical record number and "left lower alveolus." It consists of a 0.8 x 0.6

x 0.2 piece of gray-white tissue which is submitted entirely in cassette

labeled as 7AFS.

Time in formalin:

Part 8 is received fresh for intraoperative consultation labeled with the

patient' s name, initials XX, medical record number and "left lower lip." It

consists of a 2.5 x 0.3 x 0.2 cm piece of tissue which is submitted entirely

in cassette labeled as 8AFS.

Time in formalin:

Part 9 is received fresh labeled with the patient' s name, initials XX, medical record number and "left marginal mandibulectomy." It consists of a

0.6 x 0.9 x 1.1 cm portion of mandible with four defects.

Ink Code:

Black deep margin.

Section Code:

9A one margin

9B other margin

9C representative section of the mid portion.

Time in formalin:

Part 10 is received fresh labeled with the patient' s name, initials XX,

medical record number and "left neck level 1." It consists of a 6.0 x 5.0 x

2.0 cm portion of fibroadipose tissue. On dissection a submandibular gland

measuring 5.0 x 3.0 x 2.0 cm is noted.

Section Code:

10A one lymph node entirely submitted

10B submandibular gland

10C-10D representative sections of the fat

10E three possible lymph nodes

10F one lymph node

10G four possible lymph nodes

10H fat.

Time in formalin:

Part 11 is received fresh labeled with the patient' s name, initials XX,

medical record number and "left neck level 2-4." It consists of an unoriented

portion of fibroadipose tissue with lymph nodes measuring 12.0 x 8.0 x 2.0 cm.

[page 4 of 7]
Section Code:

Level 2:

- 11A one lymph node
- 11B four possible lymph nodes
- 11C four possible lymph nodes
- 11D fat.

Level 3:

- 11E six possible lymph nodes
- 11F four possible lymph nodes
- 11G four possible lymph nodes

Level 4:

- 11H two possible lymph nodes
- 11I five possible lymph nodes
- 11J six possible lymph nodes.

Time in formalin:

INTRAOPERATIVE CONSULTATION:

PART 1AGD: LEFT BUCCAL RESECTION (gross consultation)

- A. SATISFACTORY FOR ANCILLARY STUDIES.
- B. GROSS ONLY.
- C. FROM CENTER OF LESION. CARCINOMA IS WITHIN 0.1 CM OF THE INFERIOR MARGIN AND 0.6 CM FROM THE SUPERIOR MARGIN AND 0.2 CM FROM THE POSTERIOR MARGIN. ALL CUTANEOUS MARGINS ARE MORE THAN 0.5 CM OF CARCINOMA

PART 2AFS: RIGHT LOWER LIP, BIOPSY (frozen section)

- A. SATISFACTORY FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR; GRANULATION TISSUE

PART 4AFS: LEFT UPPER LIP, MARGIN, EXCISION (frozen section)

- A. SATISFACTORY FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT (

MD).

PART 5AFS: LEFT UPPER ALVEOLUS, SHAVE MARGIN, EXCISION (frozen section)

- A. SATISFACTORY FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR PRESENT

MD).

PART 6AFS: LEFT POSTERIOR BUCCAL SHAVE MARGIN (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. FOCAL MILD DYSPLASIA

PART 7AFS: LEFT LOWER ALVEOLUS, BIOPSY (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.

[page 5 of 7]
C. NO TUMOR PRESENT

MD).

PART 8AFS: LEFT LOWER LIP, BIOPSY (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES.

B. BENIGN.

C. NO TUMOR PRESENT

MD).

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by

the Department of Pathology, as required by the CLIA

'88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: left buccal resection

TUMOR SITE: Other: oral cavity, cheek

TUMOR SIZE: Greatest dimension: 4 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT4a

REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 45

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM): pMX

MARGINS: Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L): Absent

PERINEURAL INVASION: Absent

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Invasive squamous cell carcinoma..

PROCEDURE: Excision buccal lesion.

[page 6 of 7]
SPECIFIC CLINICAL QUESTION: Not answered.
OUTSIDE TISSUE DIAGNOSIS: Not answered.
PRIOR MALIGNANCY: Not answered.
CHEMORADIATION THERAPY: Not answered.
ORGAN TRANSPLANT: Not answered.
IMMUNOSUPPRESSION: Not answered.
OTHER DISEASES: Not answered.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:
Part 1: left buccal resection

Stain/	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G

Part 2: Lip biopsy, right lower

Stain	Block
H&E x 1	AFS

Part 3: Additional mucosal circumferential margin

Stain/	Block
H&E x 1	A
H&E x 1	B

Part 4: Lip, left upper

Stain/	Block
H&E x 1	AFS

Part 5: Left upper alveolus

Stain/	Block
H&E x 1	AFS

Part 6: Left posterior buccal margin

Stain/	Block
H&E x 1	AFS

Part 7: Left Lower alveolus

Stain/	Block
H&E x 1	AFS

Part 8: Lip. left lower

Stain/	Block
H&E x 1	AFS

Part 9: left marginal mandibulectomy

Stain/	Block
H&E x 1	ADR
H&E x 1	BDR
H&E x 1	CDR

Part 10: Neck Dissection, left level 1

Stain.	Block
--------	-------

[page 7 of 7]
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H

Part 11: Neck Dissection, left levels 2-4

Stain/	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	H
H&E x 1	I
H&E x 1	J
H&E x 1	K
H&E x 1	L
H&E x 1	M
H&E x 1	N

Source: NCI Genomic Data Commons file 0ff51074-dc4f-4f5e-87b9-19d5bc509b7f (TCGA-CN-A63V.2D9BA65C-231F-4D7C-BD0C-442CA26E8E7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).